Somatic mutation profile of tumor specimen MP2PRT-PAUNBE-TMP1-A (aliquot MP2PRT-PAUNBE-TMP1-A-1-0-D-A81P-36) from MP2PRT case MP2PRT-PAUNBE, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.9 years (1,044 days).
Specimen MP2PRT-PAUNBE-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 49455891-65e2-4506-9847-f77efd4a8f46.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUNBE-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUNBE-NB1-A-1-0-D-A81P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/de8959f8-65c3-426a-b201-b4acb7651d5a

The open-access MAF lists 21 somatic variants for this specimen: 17 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 3, In Frame Ins 2, 5'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMARCA4 | c.3403C>T p.R1135W | Missense Mutation (SNP) | VAF 82/399 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60795621; called by muse, mutect2, varscan2
- ADAMTS4 | c.776G>T p.R259L | Missense Mutation (SNP) | VAF 51/543 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0.079); catalogued as rs1242506429, COSV100917463; called by muse, mutect2
- ANKRD30B | c.1795del p.E599Nfs*5 | Frame Shift Del (DEL) | VAF 26/132 reads (20%) | catalogued as rs1193548518, COSV62821470; called by mutect2, pindel, varscan2
- ANO5 | c.2630A>G p.H877R | Missense Mutation (SNP) | VAF 69/228 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs767933338; called by muse, mutect2, varscan2
- CKM | c.941G>A p.R314H | Missense Mutation (SNP) | VAF 44/496 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.941); catalogued as rs1313579937, COSV99488903; called by muse, mutect2
- DCC | c.1645G>A p.E549K | Missense Mutation (SNP) | VAF 49/527 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.151); catalogued as COSV59127401; called by muse, mutect2
- GLIS3 | c.440C>T p.A147V | Missense Mutation (SNP) | VAF 43/428 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.207); catalogued as rs1277705225; called by muse, mutect2, varscan2
- JAK2 | c.2082C>G p.F694L | Missense Mutation (SNP) | VAF 57/276 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1339159756, COSV67640001; called by muse, mutect2, varscan2
- PWWP3A | c.1975G>A p.V659M (on ENST00000627377; = p.V658M on NM_032853.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 167/375 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs967539074; called by muse, mutect2, varscan2
- RPH3A | c.364G>A p.V122I (on ENST00000389385 / NM_001143854.2; = p.V118I on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 73/249 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.904); catalogued as rs555846302; called by muse, mutect2, varscan2
- SEMA5B | c.1310T>C p.L437P | Missense Mutation (SNP) | VAF 257/601 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99532180; called by muse, mutect2, varscan2
- ZNF695 | c.346A>G p.R116G | Missense Mutation (SNP) | VAF 114/379 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as rs748553970; called by muse, mutect2, varscan2
- IGKV1OR2-108 | c.352_353insGC | In Frame Ins (INS) | VAF 33/159 reads (21%) | called by mutect2, pindel*, varscan2
- IGKV3D-11 | chr2:90173412 ins CCGGGGTG | In Frame Ins (INS) | VAF 19/131 reads (15%) | called by mutect2, pindel, varscan2
- NUP93 | c.1017T>A p.N339K | Missense Mutation (SNP) | VAF 218/486 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SYK | c.1649C>T p.S550F | Missense Mutation (SNP) | VAF 50/554 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZMYM4 | c.4360G>T p.V1454L | Missense Mutation (SNP) | VAF 34/335 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CFAP46 | c.4542G>C p.L1514= | Silent (SNP) | VAF 149/549 reads (27%) | called by muse, mutect2
- LRRC66 | c.387C>T p.L129= | Silent (SNP) | VAF 88/330 reads (27%) | called by muse, mutect2, varscan2
- UNC5A | c.1662G>A p.A554= | Silent (SNP) | VAF 214/505 reads (42%) | catalogued as rs779792903; called by muse, mutect2, varscan2
- TMEM52B | c.-1G>A | 5'UTR (SNP) | VAF 24/370 reads (6%) | catalogued as rs368962696; called by muse, mutect2
